PECGS case C083-000059 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/eef0cf30-bb90-43f0-8da0-462ca70988bd

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 59 years; Year of birth: 1963; Education level: Some High School or Less.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Age at diagnosis: 59.0 years (21,550 days); AJCC pathologic stage: Stage I; Progression or recurrence: no.

Other clinical attributes
- Menopause status: Postmenopausal.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Pack years smoked: 0.

Biospecimens (2 samples)
- Sample C083-000059_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000059_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
